Somatic mutation profile of tumor specimen 59891744-2db3-4541-a86a-7f911f (aliquot 59891744-2db3-4541-a86a-7f911f_D6) from CPTAC case 01CO005, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 59891744-2db3-4541-a86a-7f911f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d46e60ef-875b-4f09-b0f9-24ae151ab136.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 26fc0181-e1ed-4853-9c67-535552 (Blood Derived Normal), aliquot 26fc0181-e1ed-4853-9c67-535552_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/627d5af6-b679-4d58-a30a-4a8320015480

The open-access MAF lists 165 somatic variants for this specimen: 109 protein-altering or splice-affecting, 36 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 36, Intron 13, Nonsense Mutation 6, Frame Shift Ins 4, RNA 3, Splice Region 2, Frame Shift Del 2, Splice Site 2, 5'Flank 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 92/326 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- AC004593.2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as COSV56100610; called by muse, mutect2, varscan2
- ADAMTS19 | c.973del p.Y325Tfs*9 | Frame Shift Del (DEL) | VAF 17/105 reads (16%) | catalogued as COSV50745256; called by mutect2, pindel, varscan2
- ADGRL2 | c.1160G>C p.R387P | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99588522; called by muse, mutect2, varscan2
- AGER | c.1037G>A p.G346E | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as rs149093508; called by muse, mutect2, varscan2
- APC | c.4219del p.S1407Vfs*8 | Frame Shift Del (DEL) | VAF 137/244 reads (56%) | catalogued as CD093645; called by mutect2, pindel, varscan2
- ARHGEF18 | c.2960C>T p.A987V (on ENST00000359920 / NM_001130955.2; = p.A883V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/550 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs753495683; called by muse, mutect2, varscan2
- ART4 | c.29_31del p.K10del | In Frame Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs759572585; called by pindel, varscan2
- BSN | c.9895C>T p.R3299C | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs781137433, COSV56514602; called by muse, mutect2
- BUD23 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375711686, COSV99736733; called by muse, mutect2, varscan2
- C10orf71 | c.4169G>A p.G1390D | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs540767420; called by muse, mutect2, varscan2
- CACHD1 | c.3550C>T p.R1184C | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs182545219, COSV51551546; called by muse, mutect2, varscan2
- CCDC103 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV53651621; called by muse, mutect2, varscan2
- CLN3 | c.820A>G p.I274V (on ENST00000360019 / NM_001286104.2; = p.I298V on NM_000086.2) | Missense Mutation (SNP) | VAF 171/438 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs1261602795; called by muse, mutect2, varscan2
- COL7A1 | c.3831G>A p.P1277= | Splice Region (SNP) | VAF 58/395 reads (15%) | catalogued as rs369349097; called by muse, mutect2, varscan2
- CUX2 | c.2302G>A p.V768M | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs202122088; called by muse, varscan2
- DCAF12L2 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs762618000, COSV63583335; called by muse, mutect2, varscan2
- DNAH7 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs565395707, COSV100414163; called by muse, mutect2, varscan2
- DOCK2 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs370529585; called by muse, mutect2, varscan2
- EEF1A2 | c.771C>T p.G257= | Splice Region (SNP) | VAF 41/289 reads (14%) | catalogued as rs1047396966; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EGR4 | c.1210G>A p.G404R (on ENST00000545030; = p.G301R on NM_001965.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs774286556; called by muse, mutect2, varscan2
- FAT3 | c.11306C>T p.T3769M | Missense Mutation (SNP) | VAF 76/100 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1323311736, COSV53095986, COSV53126111; called by muse, mutect2, varscan2
- FBXO38 | c.3118C>T p.R1040W (on ENST00000340253 / NM_205836.3; = p.R965W on NM_030793.5) | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1486690632; called by muse, mutect2, varscan2
- FLRT1 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 92/129 reads (71%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.463); catalogued as rs781063452; called by muse, mutect2, varscan2
- HMCN1 | c.13189C>T p.R4397W | Missense Mutation (SNP) | VAF 111/300 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs776115129, COSV54890766; called by muse, mutect2, varscan2
- HRNR | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs764039667; called by muse, mutect2, varscan2
- IGHE | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 76/121 reads (63%) | catalogued as rs781843520; called by muse, mutect2, varscan2
- IGSF9 | c.1501G>A p.V501I (on ENST00000368094 / NM_001135050.2; = p.V485I on NM_020789.4) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs760853772, COSV63639991; called by muse, mutect2, varscan2
- INSR | c.3485C>T p.A1162V | Missense Mutation (SNP) | VAF 204/387 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913154, CM1010226, CM930442; called by muse, mutect2, varscan2
- KCNS2 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs749919384; called by muse, mutect2, varscan2
- KIAA1109 | c.13680G>T p.M4560I | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1425917365, COSV52670909; called by muse, mutect2, varscan2
- KMT2B | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as rs766234703; called by muse, mutect2, varscan2
- KRTAP15-1 | c.59G>T p.R20M | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV100481618; called by muse, mutect2, varscan2
- MALRD1 | c.5045A>T p.E1682V | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV101035379; called by muse, mutect2, varscan2
- MEMO1 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as COSV54455032; called by muse, mutect2, varscan2
- MYH14 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759687206, COSV51833672; called by muse, mutect2, varscan2
- NIT2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as rs1406521630; called by muse, mutect2, varscan2
- NOTCH1 | c.4429G>A p.G1477S | Missense Mutation (SNP) | VAF 81/280 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1229508084; called by muse, mutect2, varscan2
- OR5A2 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 110/161 reads (68%) | SIFT tolerated (0.52); PolyPhen benign (0.164); catalogued as rs761490143; called by muse, mutect2, varscan2
- OTOGL | c.5816C>T p.T1939M (on ENST00000547103; = p.T1930M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/108 reads (70%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs371201947; called by muse, mutect2, varscan2
- PDE6C | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 173/249 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051925, COSV101008600; called by muse, mutect2, varscan2
- PKD1L1 | c.5758G>A p.G1920S | Missense Mutation (SNP) | VAF 146/199 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs772098035, COSV56958238; called by muse, mutect2, varscan2
- PMEPA1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55693554; called by muse, mutect2
- RALGAPA2 | c.2438C>A p.T813K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.055); catalogued as rs1479362605; called by muse, mutect2, varscan2
- RBMXL2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.202); catalogued as rs1406866424; called by muse, mutect2, varscan2
- SAAL1 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100253884; called by muse, mutect2, varscan2
- SLC14A2 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs267605187, COSV99675141; called by mutect2, varscan2
- SLC6A2 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 152/434 reads (35%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.506); catalogued as rs375910266; called by muse, mutect2, varscan2
- SPATA16 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 232/341 reads (68%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); catalogued as rs778336962, COSV63532712; called by muse, mutect2, varscan2
- SYNE1 | c.15682G>T p.D5228Y (on ENST00000367255 / NM_182961.4; = p.D5157Y on NM_033071.3) | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV54976955; called by mutect2, varscan2
- TDRD6 | c.2750dup p.N917Kfs*15 | Frame Shift Ins (INS) | VAF 55/234 reads (24%) | catalogued as rs765467808; called by mutect2, varscan2
- TIGD2 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 72/220 reads (33%) | catalogued as COSV57647448; called by muse, mutect2, varscan2
- TLX3 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51540093; called by muse, mutect2, varscan2
- UBASH3B | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1458210636; called by muse, mutect2, varscan2
- ZC3H12D | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs768463533; called by muse, mutect2, varscan2
- ZNF540 | c.843dup p.S282* | Frame Shift Ins (INS) | VAF 60/192 reads (31%) | catalogued as rs757107073; called by mutect2, varscan2
- AIFM3 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD26 | c.4963G>C p.E1655Q | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ANKRD30B | c.3916C>G p.L1306V | Missense Mutation (SNP) | VAF 89/296 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- APOB | c.9904T>A p.L3302I | Missense Mutation (SNP) | VAF 144/505 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ASB16 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ASPM | c.4469G>T p.C1490F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- BIRC6 | c.13202C>T p.A4401V | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- BRINP3 | c.552T>A p.Y184* | Nonsense Mutation (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2, varscan2
- CLASRP | c.1803G>A p.M601I | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- DKK2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 137/351 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNM2 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 189/694 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, varscan2
- FAM184B | c.2007G>T p.M669I | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GUCY1A1 | c.543A>C p.K181N | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- IGHV3-38 | c.61_63dup p.V21dup | In Frame Ins (INS) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- KIFC2 | c.1608G>T p.R536S | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LUZP1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LUZP1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACF1 | c.4571G>A p.G1524D | Missense Mutation (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by mutect2, varscan2
- MATN4 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 118/406 reads (29%) | PolyPhen benign (0.166); called by muse, mutect2, varscan2
- MED30 | c.336+2T>C p.X112_splice | Splice Site (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- MGAT5 | c.341C>A p.T114K | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MPLKIP | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 59/556 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MROH7 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MSH4 | c.1098C>A p.N366K | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MST1R | c.1090T>G p.S364A | Missense Mutation (SNP) | VAF 122/181 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC6 | c.5264C>G p.S1755C | Missense Mutation (SNP) | VAF 63/430 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NBEA | c.4324G>C p.V1442L | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR4D1 | c.264G>C p.E88D | Missense Mutation (SNP) | VAF 135/319 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OTUD7B | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PCDH17 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- PCDHB10 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 174/565 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PIGM | c.390T>G p.F130L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R1A | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSMA3 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PYHIN1 | c.623_624insC p.I209Yfs*19 | Frame Shift Ins (INS) | VAF 28/158 reads (18%) | called by mutect2, pindel, varscan2
- RUNDC1 | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SAFB | c.1863-1G>A p.X621_splice | Splice Site (SNP) | VAF 10/95 reads (11%) | called by mutect2, varscan2
- SAP130 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SENP6 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- SLC13A1 | c.1157C>A p.S386* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- SOX5 | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SPATA31A6 | c.1140A>T p.K380N | Missense Mutation (SNP) | VAF 201/256 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by mutect2, varscan2
- SYNE1 | c.7291G>T p.E2431* (on ENST00000367255 / NM_182961.4; = p.E2438* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 58/304 reads (19%) | called by mutect2, varscan2
- TCP10L2 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 36/312 reads (12%) | called by muse, mutect2, varscan2
- TMEM63A | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- TP53 | c.972_975dup p.E326Wfs*12 | Frame Shift Ins (INS) | VAF 100/174 reads (57%) | called by mutect2, varscan2
- TTC21B | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TTC23L | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TXLNB | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- VCAN | c.3599A>G p.K1200R | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ZC3H12B | c.1674C>G p.N558K | Missense Mutation (SNP) | VAF 135/375 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF611 | c.952A>T p.N318Y | Missense Mutation (SNP) | VAF 156/396 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADSS1 | c.1149G>A p.G383= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as COSV58274891; called by muse, mutect2, varscan2
- ANKFN1 | c.3282C>T p.D1094= (on ENST00000653862; = p.D947= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 179/386 reads (46%) | catalogued as rs996720759; called by muse, mutect2, varscan2
- ARHGDIG | c.609C>T p.T203= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as rs371686706; called by muse, mutect2, varscan2
- ARSK | c.1113T>C p.P371= | Silent (SNP) | VAF 73/185 reads (39%) | called by muse, mutect2, varscan2
- COL16A1 | c.3993C>T p.P1331= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs760926747; called by muse, mutect2, varscan2
- COL6A5 | c.429G>A p.S143= | Silent (SNP) | VAF 107/143 reads (75%) | catalogued as rs774149097; called by muse, mutect2, varscan2
- CRISPLD1 | c.408G>A p.S136= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs758076492; called by muse, mutect2, varscan2
- DNM2 | c.420C>T p.I140= | Silent (SNP) | VAF 180/638 reads (28%) | catalogued as COSV58957234; called by muse, varscan2
- FBXO11 | c.1596A>C p.S532= (on ENST00000403359 / NM_001190274.2; = p.S448= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- GFOD1 | c.468G>A p.L156= | Silent (SNP) | VAF 88/275 reads (32%) | called by muse, mutect2, varscan2
- ITGA10 | c.1861C>T p.L621= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV65197056; called by muse, mutect2, varscan2
- KCTD8 | c.225G>A p.S75= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV63592536; called by muse, mutect2, varscan2
- KIF26B | c.2550C>T p.S850= | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as rs765221697, COSV100831884; called by muse, mutect2, varscan2
- KIF5C | c.2811G>A p.T937= | Silent (SNP) | VAF 63/225 reads (28%) | catalogued as rs922422808, COSV101276193, COSV68479844; called by muse, mutect2, varscan2
- MKX | c.1041G>A p.P347= | Silent (SNP) | VAF 51/71 reads (72%) | catalogued as rs369236488, COSV65392905; called by muse, mutect2, varscan2
- NPC1L1 | c.2886C>T p.T962= | Silent (SNP) | VAF 48/387 reads (12%) | called by muse, mutect2, varscan2
- OGFR | c.309C>T p.F103= | Silent (SNP) | VAF 45/377 reads (12%) | called by muse, mutect2, varscan2
- OR8B4 | c.537C>T p.D179= | Silent (SNP) | VAF 282/398 reads (71%) | catalogued as rs61736191, COSV62069421, COSV62069927; called by muse, mutect2, varscan2
- OXR1 | c.906G>A p.K302= (on ENST00000442977 / NM_001198532.1; = p.K301= on NM_018002.3) | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- PCDH17 | c.2532C>T p.S844= | Silent (SNP) | VAF 55/100 reads (55%) | called by muse, mutect2, varscan2
- PCDH9 | c.804T>C p.G268= | Silent (SNP) | VAF 40/169 reads (24%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1710G>A p.A570= | Silent (SNP) | VAF 79/630 reads (13%) | called by muse, varscan2
- PCDHB15 | c.1023C>T p.N341= | Silent (SNP) | VAF 35/319 reads (11%) | catalogued as rs533235123, COSV50906570; called by muse, mutect2, varscan2
- PCDHB15 | c.1710G>A p.A570= | Silent (SNP) | VAF 41/564 reads (7%) | catalogued as rs781845145, COSV50926656; called by muse, mutect2
- PKD1L1 | c.5598C>T p.H1866= | Silent (SNP) | VAF 51/419 reads (12%) | catalogued as rs756940262; called by muse, mutect2, varscan2
- PKHD1 | c.8052G>A p.Q2684= | Silent (SNP) | VAF 64/555 reads (12%) | called by muse, mutect2, varscan2
- PLK5 | c.600C>T p.P200= | Silent (SNP) | VAF 46/230 reads (20%) | catalogued as rs1226854716; called by muse, mutect2, varscan2
- RAB34 | c.255T>C p.I85= | Silent (SNP) | VAF 75/447 reads (17%) | called by muse, mutect2, varscan2
- RAD54L2 | c.537C>G p.A179= | Silent (SNP) | VAF 62/112 reads (55%) | called by mutect2, varscan2
- RYR3 | c.10045C>A p.R3349= (on ENST00000389232; = p.R3350= on NM_001036.6) | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs377377472, COSV66800715; called by muse, mutect2
- SALL3 | c.2973G>A p.A991= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs372071983; called by muse, mutect2, varscan2
- SRCIN1 | c.2550C>T p.R850= (on ENST00000621492; = p.R816= on NM_025248.3) | Silent (SNP) | VAF 55/113 reads (49%) | catalogued as rs778344979; called by muse, mutect2, varscan2
- TNS1 | c.1506C>T p.D502= | Silent (SNP) | VAF 98/391 reads (25%) | catalogued as rs368231680; called by muse, mutect2, varscan2
- UACA | c.2073G>A p.K691= | Silent (SNP) | VAF 113/171 reads (66%) | catalogued as COSV59854662; called by muse, mutect2, varscan2
- UGGT2 | c.3549C>G p.L1183= | Silent (SNP) | VAF 49/113 reads (43%) | called by muse, mutect2, varscan2
- ZADH2 | c.6G>T p.L2= | Silent (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- ANK2 | c.85-57040dup | Intron (INS) | VAF 79/233 reads (34%) | called by mutect2, varscan2
- ANKRD42 | c.502+1275C>T | Intron (SNP) | VAF 64/179 reads (36%) | called by muse, mutect2, varscan2
- BSCL2 | chr11:62707204 del CGAG | 5'Flank (DEL) | VAF 38/344 reads (11%) | called by mutect2, pindel, varscan2
- CNGB3 | c.-35A>T | 5'UTR (SNP) | VAF 118/381 reads (31%) | called by muse, mutect2, varscan2
- COL5A1 | c.654+7556G>T | Intron (SNP) | VAF 50/198 reads (25%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.3808C>A | RNA (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- ENY2 | c.230-709G>A | Intron (SNP) | VAF 50/191 reads (26%) | called by muse, mutect2, varscan2
- FAM90A20P | n.1015G>A | RNA (SNP) | VAF 16/413 reads (4%) | catalogued as rs1270839621; called by muse, mutect2
- FCHO2 | c.914+724T>C | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- GSDME | c.404+22T>G | Intron (SNP) | VAF 44/316 reads (14%) | called by muse, mutect2, varscan2
- KIF28P | n.2015C>T | RNA (SNP) | VAF 122/330 reads (37%) | called by muse, mutect2, varscan2
- KSR1 | c.1510+499T>C | Intron (SNP) | VAF 40/224 reads (18%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-9286C>T | Intron (SNP) | VAF 108/229 reads (47%) | catalogued as rs1306583145, COSV58273190; called by muse, mutect2, varscan2
- NSMCE4A | c.293-9T>A | Intron (SNP) | VAF 18/125 reads (14%) | catalogued as rs1377214303; called by muse, mutect2, varscan2
- PEG10 | c.*750C>T | 3'UTR (SNP) | VAF 48/530 reads (9%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159967 C>T | 5'Flank (SNP) | VAF 25/82 reads (30%) | catalogued as rs74692475; called by muse, mutect2, varscan2
- SMTN | c.1632+634G>A | Intron (SNP) | VAF 76/181 reads (42%) | catalogued as rs945997053; called by muse, mutect2, varscan2
- SNCAIP | c.58-2732G>C | Intron (SNP) | VAF 49/156 reads (31%) | called by muse, mutect2, varscan2
- TTLL9 | c.706-168G>A | Intron (SNP) | VAF 82/237 reads (35%) | catalogued as rs370673456; called by muse, mutect2, varscan2
- TTN | c.10360+1240T>C | Intron (SNP) | VAF 18/191 reads (9%) | called by muse, mutect2
